Somatic mutation profile of tumor specimen TCGA-24-2030-01A (aliquot TCGA-24-2030-01A-01W-0722-08) from TCGA case TCGA-24-2030, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-24-2030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 194075f3-bcab-4148-afc1-93a22cc0ba61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2030-10A (Blood Derived Normal), aliquot TCGA-24-2030-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/484fcef5-9d95-44fd-bb1d-4ae2a112df2b

The open-access MAF lists 67 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 43, Silent 15, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 26/38 reads (68%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGK | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 233/274 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1050547126, COSV62595322; called by muse, mutect2, varscan2
- ANO8 | c.3047G>T p.G1016V | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as rs1487438561, COSV50189166; called by muse, mutect2, varscan2
- APOBEC3A | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs894016096, COSV50779593; called by muse, mutect2, varscan2
- ARHGEF3 | c.978C>G p.D326E | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56329835; called by muse, mutect2, varscan2
- ARHGEF7 | c.1840G>A p.A614T (on ENST00000375741 / NM_001113511.2; = p.A436T on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs1348495090, COSV54538939; called by muse, mutect2
- BCO2 | c.1322C>A p.A441D | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV100730251; called by muse, varscan2
- BIRC6 | c.12758C>T p.A4253V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as COSV70203037; called by muse, mutect2, varscan2
- CCDC87 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100039803; called by muse, mutect2, varscan2
- CHRNA5 | c.309G>C p.W103C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1182689078, COSV55139535; called by muse, mutect2
- CPT1C | c.1816A>G p.T606A | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54920896; called by muse, mutect2
- CYP7A1 | c.1401G>C p.L467F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV56964627; called by mutect2, varscan2
- DDX58 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs769162572, COSV65883751; called by muse, mutect2, varscan2
- DIP2A | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.071); catalogued as COSV100595343; called by muse, mutect2
- ENAM | c.1051A>G p.R351G | Missense Mutation (SNP) | VAF 68/210 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV68536586; called by muse, mutect2, varscan2
- GLI2 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV58046921; called by muse, mutect2, varscan2
- GNPAT | c.1867T>G p.L623V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64153661, COSV64153911; called by muse, mutect2, varscan2
- HNF4G | c.1142G>A p.G381D (on ENST00000354370 / NM_001330561.2; = p.G428D on NM_004133.5) | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.558); catalogued as rs765840318, COSV100584867, COSV62971287; called by muse, mutect2, varscan2
- MRPS5 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99720706; called by muse, mutect2, varscan2
- NDRG1 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs750779893, COSV60485067; called by muse, mutect2, varscan2
- PCNT | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV64030832; called by muse, mutect2, varscan2
- PCNT | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV64030837; called by muse, mutect2, varscan2
- PLCB1 | c.2108G>C p.G703A | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62060149; called by muse, mutect2, varscan2
- PLEKHB1 | c.543dup p.N182Qfs*102 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs747647640; called by pindel, varscan2
- PSMD10 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54264448; called by muse, varscan2
- RASGRF2 | c.2121C>A p.N707K | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV54134775; called by muse, mutect2, varscan2
- RFPL3 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.017); catalogued as COSV99966944; called by muse, mutect2
- RPS6KA1 | c.1214A>G p.Q405R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as COSV65177156; called by muse, mutect2, varscan2
- SAGE1 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1556606671, COSV100186598, COSV61011517; called by muse, mutect2
- SEC23A | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as COSV56976517; called by muse, mutect2, varscan2
- SERINC5 | c.1050G>T p.L350F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV72596721; called by muse, varscan2
- SLC1A2 | c.1188T>G p.I396M | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99554107; called by muse, mutect2
- TAP1 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs765271187, COSV62754684; called by muse, mutect2, varscan2
- TASOR | c.3347T>C p.I1116T (on ENST00000355628 / NM_001365636.2; = p.I740T on NM_015224.3) | Missense Mutation (SNP) | VAF 52/556 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369681222; called by muse, mutect2
- TGIF2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100872271; called by muse, mutect2, varscan2
- TMEM131 | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV51781335; called by muse, mutect2, varscan2
- TRIM23 | c.1331A>C p.E444A | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV51553286; called by muse, mutect2, varscan2
- TSPAN33 | c.519C>G p.C173W | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56827106; called by muse, mutect2, varscan2
- USP15 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV54795686; called by muse, mutect2, varscan2
- UTP18 | c.1631A>C p.K544T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV99834627; called by muse, mutect2, varscan2
- VCAN | c.8704G>C p.E2902Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV54111168, COSV54116249; called by muse, mutect2, varscan2
- VEGFA | c.334C>T p.H112Y (on ENST00000523873 / NM_001171623.1; = p.H292Y on NM_003376.6) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as COSV57878283; called by muse, mutect2, varscan2
- ZC2HC1C | c.103T>A p.Y35N | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV53172956; called by muse, mutect2, varscan2
- ZFP69B | c.1591A>G p.S531G | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.071); catalogued as COSV64315823; called by muse, mutect2, varscan2
- ZNF280C | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs780382501, COSV63969060; called by muse, mutect2, varscan2
- ZNF529 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1245924437, COSV61901259; called by muse, mutect2, varscan2
- ABCB7 | c.372del p.M124Ifs*30 (on ENST00000373394 / NM_001271696.3; = p.M125Ifs*30 on NM_004299.6) | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- ATAD5 | c.816_817del p.H274Qfs*4 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, pindel, varscan2
- F5 | c.2351_2353del p.S784del | In Frame Del (DEL) | VAF 67/375 reads (18%) | called by mutect2, pindel, varscan2
- NPFF | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, varscan2
- TRPV2 | c.1742dup p.E582Gfs*74 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- TSSK3 | c.381del p.C128Vfs*20 | Frame Shift Del (DEL) | VAF 21/116 reads (18%) | called by mutect2, pindel, varscan2
- ACE2 | c.1101C>T p.D367= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as rs750477605, COSV53026365; called by muse, mutect2, varscan2
- ASS1 | c.528G>A p.K176= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100752538; called by muse, mutect2
- ATP2A1 | c.2001G>C p.R667= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV100706755, COSV100706862; called by muse, mutect2
- B3GALT4 | c.43C>T p.L15= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV101005570; called by mutect2, varscan2
- CEP192 | c.3060G>A p.Q1020= | Silent (SNP) | VAF 70/257 reads (27%) | catalogued as COSV100380710; called by muse, mutect2, varscan2
- DMD | c.10659C>A p.P3553= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV58931488; called by muse, mutect2, varscan2
- GALNTL6 | c.1770T>A p.T590= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV101560152; called by muse, mutect2, varscan2
- GJB4 | c.342G>A p.P114= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs146404415; called by muse, mutect2, varscan2
- INPP5K | c.849C>T p.P283= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs748453410, COSV100233576; called by muse, mutect2, varscan2
- MAGEB6 | c.417C>A p.S139= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV66872656; called by muse, mutect2, varscan2
- MOB4 | c.45G>A p.P15= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs150417095; called by muse, mutect2, varscan2
- PRICKLE2 | c.2160C>A p.P720= (on ENST00000295902; = p.P664= on NM_198859.4) | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV55769346; called by muse, mutect2, varscan2
- RIOK1 | c.348T>C p.F116= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV53572870; called by muse, mutect2
- TMEM132D | c.2070C>A p.I690= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as COSV67161363; called by muse, mutect2, varscan2
- ZNF622 | c.1338G>A p.Q446= | Silent (SNP) | VAF 81/152 reads (53%) | catalogued as COSV58074730; called by muse, mutect2, varscan2
